Somatic mutation profile of tumor specimen TARGET-20-PASGZV-03A (aliquot TARGET-20-PASGZV-03A-01D) from TARGET case TARGET-20-PASGZV, project TARGET-AML (Acute Myeloid Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 1.6 years (580 days).
Specimen TARGET-20-PASGZV-03A: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 92d534b8-3240-42c1-8267-f0b3f2498100.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-20-PASGZV-14A (Bone Marrow Normal), aliquot TARGET-20-PASGZV-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e77b33f6-29bb-4fa3-a594-59905e996a77

The open-access MAF lists 2 somatic variants for this specimen: 1 protein-altering or splice-affecting, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: 3'UTR 1, Missense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PTPN11 | c.179G>T p.G60V | Missense Mutation (SNP) | VAF 45/222 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs397507509, CD041931, CM021126, CX060726, COSV100692385, COSV61005028, COSV61006397; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- CTNNB1 | c.*1028C>T | 3'UTR (SNP) | VAF 54/272 reads (20%) | called by muse, mutect2, varscan2
